Gene-level copy-number profile of specimen HCM-CSHL-1269-C18-85M from HCMI case HCM-CSHL-1269-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IVB; Tumor grade: G2; Age at diagnosis: 49.4 years (18,035 days).
Specimen HCM-CSHL-1269-C18-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file bad619d8-dfaa-47d7-9f7e-1ce2f6bfc9d4.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-1269-C18-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,230 have no estimate.
https://portal.gdc.cancer.gov/files/5ef75316-4f3a-4672-8073-01c482b63d8d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 2,486; copy number 2: 23,949; copy number 3: 20,730; copy number 4: 8,502; copy number 5: 2,725.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:6,873,899–6,874,005, 1 gene (within-gene range 0–2): RNU6-457P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,725 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:87,221,113–87,253,750, 2 genes, copy number 5: CENPNP1, LINC01955.
- chr2:87,439,523–87,459,044, 1 gene, copy number 5 (within-gene range 4–5): LINC01943.
- chr2:90,100,236–90,115,402, 2 genes, copy number 5 (within-gene range 3–5): IGKV1D-16, IGKV3D-15.
- chr3:66,133,610–67,011,210, 7 genes, copy number 5: SLC25A26, RNU6-787P, RN7SL482P, LRIG1, AC104440.1, RPL21P41, KBTBD8.
- chr13:18,467,172–114,337,626, 1,330 genes, copy number 5 (broad region; genes not listed).
- chr20:87,250–13,996,443, 277 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr20:16,177,933–64,327,972, 1,106 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,486. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
